Somatic mutation profile of tumor specimen TCGA-DK-A3X2-01A (aliquot TCGA-DK-A3X2-01A-11D-A22Z-08) from TCGA case TCGA-DK-A3X2, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 85.3 years (31,160 days).
Specimen TCGA-DK-A3X2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8643b913-889a-4c7a-b1a1-7700002ed00d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A3X2-10A (Blood Derived Normal), aliquot TCGA-DK-A3X2-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69509bb2-5497-445f-b469-e0d982899aad

The open-access MAF lists 134 somatic variants for this specimen: 107 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 26, Frame Shift Del 5, Frame Shift Ins 4, Nonsense Mutation 4, 3'UTR 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAT3 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs869312890, CM150604, COSV52886109; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 39/41 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1935A>T p.K645N | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52198717; called by muse, mutect2, varscan2
- ABCC12 | c.391A>C p.I131L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV60913063; called by muse, mutect2, varscan2
- ALOX5 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV65551932; called by muse, mutect2, varscan2
- ANKRD17 | c.5895A>C p.L1965F | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV58218410; called by muse, mutect2, varscan2
- ARID1A | c.2229_2248del p.S744Rfs*66 | Frame Shift Del (DEL) | VAF 22/120 reads (18%) | catalogued as COSV61375200; called by mutect2, pindel
- ASIC2 | c.148G>A p.V50M | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs753583147, COSV63301407; called by muse, varscan2
- BAP1 | c.814C>T p.Q272* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV56233960; called by muse, mutect2, varscan2
- BAP1 | c.551A>C p.D184A | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56232881, COSV56238511; called by muse, mutect2, varscan2
- BCAT2 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753795402, COSV60272270; called by muse, mutect2, varscan2
- BDP1 | c.2130G>C p.K710N | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV62430615, COSV62433288; called by muse, mutect2, varscan2
- BTF3 | c.215G>C p.R72T (on ENST00000380591 / NM_001037637.1; = p.R28T on NM_001207.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV60063324; called by muse, mutect2, varscan2
- CACNA2D4 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199886801; called by muse, mutect2, varscan2
- CELA3B | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61403703; called by muse, mutect2
- CELSR1 | c.2384C>T p.T795I | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99416972; called by muse, mutect2
- CEP170B | c.2818G>A p.G940R (on ENST00000453495; = p.G869R on NM_015005.3) | Missense Mutation (SNP) | VAF 110/115 reads (96%) | SIFT tolerated (0.29); PolyPhen benign (0.299); catalogued as COSV69024055; called by muse, mutect2, varscan2
- CFHR5 | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV99888007; called by muse, mutect2, varscan2
- CHD5 | c.5444C>T p.T1815M | Missense Mutation (SNP) | VAF 69/111 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs573215215, COSV52409305; called by muse, mutect2, varscan2
- CNST | c.588A>G p.I196M | Missense Mutation (SNP) | VAF 65/94 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.352); catalogued as COSV63620201; called by muse, mutect2, varscan2
- CNTLN | c.3706G>A p.E1236K | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV52073990, COSV52088849; called by muse, mutect2, varscan2
- COBL | c.2310C>G p.F770L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV54342827; called by muse, mutect2, varscan2
- CREBBP | c.5060C>T p.S1687F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as CM123180, COSV52119465; called by muse, mutect2, varscan2
- CYP2B6 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV57843236; called by muse, mutect2, varscan2
- DHX35 | c.1588C>A p.H530N | Missense Mutation (SNP) | VAF 77/181 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV52668339, COSV52669328; called by muse, mutect2, varscan2
- DNAH17 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 189/435 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs368828778; called by muse, mutect2, varscan2
- DNAH5 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as rs140388814; called by muse, mutect2, varscan2
- ENAM | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 39/88 reads (44%) | catalogued as COSV101252929; called by muse, mutect2, varscan2
- EYA4 | c.812C>G p.P271R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV100765219, COSV62046800; called by muse, mutect2
- F7 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 103/130 reads (79%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs181538903, COSV60645093; called by muse, mutect2, varscan2
- FAM47B | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 92/94 reads (98%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.556); catalogued as rs1218309541, COSV61453239; called by muse, mutect2, varscan2
- FGFR2 | c.1150G>C p.G384R | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as CM960654, COSV60640087, COSV60649627; called by muse, mutect2
- FRMPD2 | c.139G>C p.D47H | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.962); catalogued as COSV100563800, COSV59716970; called by muse, mutect2, varscan2
- GALNT11 | c.627C>A p.Y209* | Nonsense Mutation (SNP) | VAF 44/103 reads (43%) | catalogued as COSV100231651; called by muse, mutect2, varscan2
- GATA4 | c.1027G>T p.A343S | Missense Mutation (SNP) | VAF 76/236 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58733010; called by muse, varscan2
- GIMAP1 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as COSV56187749; called by muse, mutect2, varscan2
- GLI3 | c.3350C>T p.P1117L | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs531098202, COSV67887231, COSV67889919; called by muse, mutect2, varscan2
- GRIK5 | c.2509G>A p.E837K | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs782084387, COSV53477119; called by muse, mutect2, varscan2
- GRM6 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as rs371304642; called by muse, mutect2, varscan2
- HECTD4 | c.11188G>C p.E3730Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.242); catalogued as COSV101107939, COSV66389896; called by muse, mutect2, varscan2
- HEXIM1 | c.649_651del p.E217del | In Frame Del (DEL) | VAF 42/224 reads (19%) | catalogued as rs1329247661; called by pindel, varscan2
- HNRNPU | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV51690416; called by muse, mutect2, varscan2
- IRS2 | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs757728267, COSV65478374; called by muse, mutect2, varscan2
- ITGAM | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1219753409, COSV54935958; called by muse, mutect2, varscan2
- KCNH4 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1057461290, COSV52916572; called by muse, mutect2, varscan2
- KCNH6 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as COSV59002463; called by muse, mutect2, varscan2
- KPRP | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV64221392; called by muse, mutect2
- LAMA5 | c.5113-1G>A p.X1705_splice | Splice Site (SNP) | VAF 27/135 reads (20%) | catalogued as COSV99438244; called by muse, mutect2
- LARP7 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100134985; called by muse, mutect2, varscan2
- LRP3 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.015); catalogued as COSV53503336; called by muse, mutect2, varscan2
- LRRN3 | c.862G>C p.E288Q | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57818446, COSV57819786; called by muse, mutect2
- MAMLD1 | c.1334C>T p.S445F | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53373700; called by muse, mutect2, varscan2
- METTL6 | c.128A>G p.K43R | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.047); catalogued as COSV67541993; called by muse, mutect2, varscan2
- MICALL2 | c.2005G>A p.V669I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs369197156; called by muse, mutect2, varscan2
- MYH7B | c.4879A>G p.K1627E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52678612; called by muse, mutect2, varscan2
- MYOM1 | c.3727A>C p.T1243P | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as COSV55289404; called by muse, mutect2, varscan2
- NAGLU | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 98/239 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.867); catalogued as rs534847909, COSV56794551; called by muse, mutect2, varscan2
- NCAM2 | c.2447C>A p.P816Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV53067192; called by muse, mutect2, varscan2
- NDNF | c.1442A>C p.Y481S | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65633134; called by muse, mutect2, varscan2
- NELL2 | c.2242G>C p.E748Q | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs749939986, COSV61572550; called by muse, mutect2, varscan2
- NODAL | c.944C>G p.P315R | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54660889; called by muse, mutect2
- OBSCN | c.15085G>A p.E5029K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1426860968, COSV52761852; called by muse, mutect2, varscan2
- PCDH10 | c.361T>A p.S121T | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV52091434; called by muse, mutect2, varscan2
- PINX1 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 268/493 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as rs374613074; called by muse, mutect2, varscan2
- PMS2 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs876658863, COSV56220896; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2
- PPP2R2A | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV60096471; called by muse, mutect2, varscan2
- PSG2 | c.791A>G p.N264S | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV61544951; called by muse, mutect2, varscan2
- PSMC2 | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV53007043; called by muse, mutect2, varscan2
- PTK2 | c.1870C>G p.Q624E | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV61784359; called by muse, mutect2
- PTPRZ1 | c.2407G>A p.V803I | Missense Mutation (SNP) | VAF 137/322 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV66434529; called by muse, mutect2, varscan2
- PYHIN1 | c.1457A>G p.N486S | Missense Mutation (SNP) | VAF 37/133 reads (28%) | PolyPhen benign (0); catalogued as rs781200351, COSV63730499; called by muse, mutect2, varscan2
- R3HDM2 | c.1116G>C p.R372S | Missense Mutation (SNP) | VAF 63/281 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV61287269, COSV61287499; called by muse, mutect2, varscan2
- RAC1 | c.76A>G p.N26D | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.229); catalogued as COSV61822512; called by muse, mutect2, varscan2
- RPUSD4 | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 83/331 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV53599070; called by muse, mutect2, varscan2
- RTN4RL1 | c.1111G>A p.G371R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs369151936; called by muse, mutect2, varscan2
- RXRB | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63399634; called by muse, mutect2, varscan2
- RYR2 | c.4084G>A p.D1362N | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV63677454; called by muse, mutect2, varscan2
- SH3TC1 | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 25/25 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756622184, COSV55283178; called by muse, mutect2, varscan2
- SHROOM2 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 20/23 reads (87%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as COSV66605687; called by muse, mutect2, varscan2
- SLC27A1 | c.589G>T p.G197W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV53096678, COSV53100006; called by muse, mutect2, varscan2
- SLC30A4 | c.26G>C p.R9P | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV56005572, COSV56005581; called by muse, mutect2, varscan2
- SNRNP35 | c.346G>T p.V116F | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV63471897; called by muse, mutect2, varscan2
- STAG2 | c.301_302del p.D101Lfs*8 | Frame Shift Del (DEL) | VAF 53/66 reads (80%) | catalogued as COSV54355621; called by mutect2, pindel, varscan2
- STK10 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 59/99 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV51572874; called by muse, mutect2, varscan2
- TCHH | c.2912A>G p.E971G | Missense Mutation (SNP) | VAF 120/444 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV64274030; called by muse, mutect2, varscan2
- TGOLN2 | c.127C>T p.H43Y | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1400519043, COSV56405756; called by muse, mutect2, varscan2
- TIAM2 | c.4983C>G p.F1661L (on ENST00000529824; = p.F1632L on NM_012454.3) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51639467, COSV51641314; called by muse, mutect2, varscan2
- TLN1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59206382; called by muse, mutect2
- TLR8 | c.81A>C p.E27D (on ENST00000218032 / NM_138636.5; = p.E45D on NM_016610.4) | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.108); catalogued as COSV54317315; called by muse, mutect2, varscan2
- TNR | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767681144, COSV54879266; called by muse, mutect2, varscan2
- TPO | c.2196G>A p.W732* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100219817; called by muse, mutect2
- VPS39 | c.1609G>A p.E537K (on ENST00000348544 / NM_001301138.2; = p.E526K on NM_015289.5) | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.188); catalogued as COSV58788875; called by muse, mutect2, varscan2
- WDR83 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs377575721; called by muse, mutect2, varscan2
- WWP1 | c.391C>G p.Q131E | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (0.99); PolyPhen benign (0.09); catalogued as COSV55358164; called by muse, mutect2, varscan2
- ZBTB8A | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs767658676, COSV100331496, COSV57142298; called by muse, mutect2, varscan2
- ZDHHC18 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs1359408015, COSV65145264; called by muse, mutect2, varscan2
- ZFPL1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs753950176, COSV51869117; called by muse, mutect2, varscan2
- ZNF292 | c.3392_3399del p.K1131Tfs*4 | Frame Shift Del (DEL) | VAF 27/31 reads (87%) | catalogued as COSV60537741; called by mutect2, pindel, varscan2
- ZNF808 | c.1483A>T p.R495W | Missense Mutation (SNP) | VAF 77/127 reads (61%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.666); catalogued as COSV63119388; called by muse, mutect2, varscan2
- ZP3 | c.640G>A p.V214M (on ENST00000394857 / NM_001110354.2; = p.V163M on NM_007155.6) | Missense Mutation (SNP) | VAF 74/226 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60632084; called by muse, mutect2, varscan2
- LACTB | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- PLXNA2 | c.3194dup p.N1065Kfs*24 | Frame Shift Ins (INS) | VAF 18/103 reads (17%) | called by mutect2, pindel, varscan2
- RB1 | c.982_983del p.N328* | Frame Shift Del (DEL) | VAF 28/36 reads (78%) | called by mutect2, pindel, varscan2
- VPS26B | c.96del p.K33Rfs*18 | Frame Shift Del (DEL) | VAF 19/94 reads (20%) | called by mutect2, pindel, varscan2
- ZFP36L1 | c.98dup p.C34Lfs*41 | Frame Shift Ins (INS) | VAF 36/52 reads (69%) | called by mutect2, pindel, varscan2
- ZNF507 | c.1176dup p.G393Rfs*4 | Frame Shift Ins (INS) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- ZNF644 | c.192dup p.S65Ifs*6 | Frame Shift Ins (INS) | VAF 25/187 reads (13%) | called by mutect2, pindel, varscan2
- ATP8B4 | c.3426C>A p.I1142= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as COSV52713148; called by muse, mutect2, varscan2
- CNTLN | c.3801G>A p.Q1267= | Silent (SNP) | VAF 98/99 reads (99%) | catalogued as COSV52074023; called by muse, mutect2, varscan2
- COPA | c.3018C>T p.L1006= | Silent (SNP) | VAF 86/419 reads (21%) | catalogued as COSV54100918; called by muse, mutect2, varscan2
- DNAH2 | c.10830C>T p.C3610= | Silent (SNP) | VAF 61/62 reads (98%) | catalogued as rs143386308; called by muse, mutect2, varscan2
- EXT1 | c.453G>T p.A151= | Silent (SNP) | VAF 106/337 reads (31%) | catalogued as rs780843781, COSV65477606, COSV65480929; called by muse, mutect2, varscan2
- FAM193A | c.828G>A p.Q276= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV61192805; called by muse, mutect2, varscan2
- FBP2 | c.156C>T p.A52= | Silent (SNP) | VAF 44/47 reads (94%) | catalogued as rs769142942, COSV64694553; called by muse, mutect2, varscan2
- FETUB | c.1017G>T p.L339= | Silent (SNP) | VAF 19/250 reads (8%) | catalogued as COSV54005294; called by muse, mutect2
- GPR158 | c.2838A>C p.S946= | Silent (SNP) | VAF 84/240 reads (35%) | catalogued as COSV66268073; called by muse, mutect2, varscan2
- GSX2 | c.642C>G p.L214= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as COSV58842703; called by muse, mutect2, varscan2
- H3C4 | c.174G>C p.S58= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as COSV100587226, COSV61911782; called by muse, mutect2
- HSD17B2 | c.954C>T p.F318= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV52275324; called by muse, mutect2, varscan2
- ITGA6 | c.2679G>A p.Q893= (on ENST00000442250; = p.Q854= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV51222212; called by muse, mutect2, varscan2
- KHDC3L | c.477G>A p.S159= | Silent (SNP) | VAF 59/64 reads (92%) | catalogued as rs993890975, COSV64863142; called by muse, mutect2, varscan2
- LARP7 | c.1596T>C p.Y532= | Silent (SNP) | VAF 57/80 reads (71%) | catalogued as COSV60520629; called by muse, mutect2, varscan2
- MCM3AP | c.2481C>T p.F827= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV52438515; called by muse, mutect2, varscan2
- OR14C36 | c.495C>T p.P165= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV58600913; called by muse, mutect2, varscan2
- RNF213 | c.6288C>T p.I2096= | Silent (SNP) | VAF 37/202 reads (18%) | catalogued as rs773708335, COSV60394635; called by muse, mutect2, varscan2
- SALL3 | c.3327G>A p.T1109= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1463633441, COSV73305940; called by muse, mutect2, varscan2
- SLC5A5 | c.1176C>G p.L392= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV55832302; called by muse, mutect2, varscan2
- SLCO1A2 | c.1566C>T p.F522= | Silent (SNP) | VAF 34/46 reads (74%) | catalogued as COSV56600031; called by muse, mutect2, varscan2
- SMTNL1 | c.1195C>A p.R399= (on ENST00000399154; = p.R436= on NM_001105565.2) | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV67699496; called by muse, mutect2, varscan2
- SNAP47 | c.981G>A p.L327= | Silent (SNP) | VAF 48/167 reads (29%) | catalogued as COSV59917492; called by muse, mutect2, varscan2
- XIRP2 | c.5502A>G p.L1834= (on ENST00000628543; = p.L2009= on NM_152381.6) | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99738871; called by muse, mutect2
- ZC3H3 | c.2329C>T p.L777= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99367435; called by muse, mutect2, varscan2
- ZNF649 | c.627C>T p.S209= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV56815013; called by muse, mutect2
- ANKRD13D | c.*741C>T | 3'UTR (SNP) | VAF 59/121 reads (49%) | catalogued as rs762455831, COSV57751635, COSV57753982; called by muse, mutect2, varscan2
